TCGA case TCGA-BR-4361 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/29ed984c-74b5-4016-a649-c32e5d1d9869

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Russia; Age at index: 66 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 66.4 years (24,260 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Days to last follow up: 0 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 8.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 0.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-4361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 3.4; Intermediate dimension: 1.1; Shortest dimension: 0.5.
  Slide TCGA-BR-4361-01A-01-BS1: Section location: Bottom; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 5; Percent necrosis: 3; Percent stromal cells: 18.
  Slide TCGA-BR-4361-01A-01-TS1: Section location: Top; Percent tumor cells: 69; Percent tumor nuclei: 80; Percent normal cells: 8; Percent necrosis: 3; Percent stromal cells: 20.
- Sample TCGA-BR-4361-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-4361-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2.2; Intermediate dimension: 1.3; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; Cancer procurement city: Ryazan; Antireflux treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 0 days; disease-specific survival: no event (censored), 0 days; progression-free interval: no event (censored), 0 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-4361-01A-01D-1155-01): tumor purity 0.67, ploidy 2.04, whole-genome doublings 0.
